TCGA case TCGA-75-5146 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Ontario Institute for Cancer Research (OICR). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d276b62-5e64-48fb-b2ce-5192b511fe37

Demographics
Sex at birth: male; Country of residence at enrollment: Canada; Vital status: Alive.

Diagnoses (2)
1. Bronchiolo-alveolar carcinoma, non-mucinous (the primary disease): ICD-O-3 morphology code: 8252/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary (histology not recorded by GDC). Days to diagnosis: 1,773 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 2,368 days (6.5 years); Disease response: Tumor Free.
- Disease response: Tumor Free; Timepoint: Follow-up.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1987.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-75-5146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.5; Shortest dimension: 0.3.
  Slide TCGA-75-5146-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-75-5146-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-75-5146-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-75-5146-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Performance status timing: Adjuvant therapy.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2, New neoplasm event types: New tumor event type: New Primary Tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,368 days; disease-specific survival: no event (censored), 2,368 days; disease-free interval: no event (censored), 2,368 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,773 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-75-5146-01A-01D-1624-01): tumor purity 0.58, ploidy 1.78, whole-genome doublings 0.
